Gene-level copy-number profile of tumor specimen TCGA-68-8251-01A from TCGA case TCGA-68-8251, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 78.7 years (28,739 days).
Specimen TCGA-68-8251-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.44e9d55d-0d78-4551-9bfe-c84bb1628135.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-68-8251-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cf04f6ca-2187-4548-89e5-9fbbde4547fe

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 103; copy number 1: 31,812; copy number 2: 26,418; copy number 3: 1,481; copy number 18: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-68-8251-01A-11D-2292-01): tumor purity 0.33, ploidy 3.01, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 103 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:3,700,814–4,467,273, 5 genes (within-gene range 0–1): SUMF1, LRRN1, AC023480.1, PNPT1P1, AC023483.1.
- chr9:21,802,636–22,128,103, 14 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr14:22,052,514–22,526,906, 84 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 1,485 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:114,314,500–115,147,288, 1 gene, copy number 3 (within-gene range 2–3): ZBTB20.
- chr3:114,684,580–176,867,838, 1,025 genes, copy number 3 (broad region; genes not listed).
- chr3:178,960,121–198,222,513, 451 genes, copy number 3 (broad region; genes not listed).
- chr8:127,289,817–127,742,951, 8 genes, copy number 3–18: CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.

Autosomal genes at a single copy (total copy number 1): 29,391. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
